Gene-level copy-number profile of tumor specimen TARGET-40-PANVJJ-01A from TARGET case TARGET-40-PANVJJ, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.8 years (5,044 days).
Specimen TARGET-40-PANVJJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.288fe8de-c59b-5f4d-b81d-c680b27c31f1.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PANVJJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 365 have no estimate.
https://portal.gdc.cancer.gov/files/d3714a1c-d4b5-4348-8067-f2b4458192f9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 562; copy number 1: 4,168; copy number 2: 23,303; copy number 3: 18,045; copy number 4: 10,627; copy number 5: 2,124; copy number 6: 605; copy number 7: 428; copy number 8: 396.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,590,487–248,919,946, 20 genes: OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P.
- chr3:175,234,861–175,271,096, 1 gene: NAALADL2-AS2.
- chr6:101,430,411–101,454,245, 2 genes: ACTG1P18, AP002528.1.
- chr14:79,072,132–79,074,767, 1 gene: AC026888.1.
- chr14:99,971,449–100,144,236, 1 gene (within-gene range 0–3): EVL.
- chr14:99,977,115–100,109,753, 4 genes: AL133368.2, AL157912.1, MIR151B, MIR342.
- chr17:7,613,946–7,885,238, 13 genes: SHBG, SAT2, ATP1B2, TP53, WRAP53, EFNB3, DNAH2, RPL29P2, KDM6B, TMEM88, NAA38, CYB5D1, AC104581.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,075 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:5,086,459–5,090,899, 1 gene, copy number 5: LINC02782.
- chr1:173,714,941–175,204,849, 35 genes, copy number 7 (within-gene range 4–7): KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2, GAS5, GAS5-AS1, ZBTB37, SERPINC1, RNA5SP67, RC3H1, RNA5SP68, RC3H1-IT1, LINC02776, RPL30P1, RABGAP1L-DT, RABGAP1L, AL022400.1, GPR52, BANF1P4, NDUFAF4P4, Z99127.2, RABGAP1L-IT1, Z99127.1, RABGAP1L-AS1, RNU6-307P, Z99127.3, CACYBP, MRPS14, Y_RNA, ENTR1P2, TNN, KIAA0040, AL008626.1.
- chr2:88,811,186–88,861,563, 1 gene, copy number 7 (within-gene range 2–7): AC244205.1.
- chr2:88,857,161–89,245,596, 38 genes, copy number 7: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr4:53,265,461–58,118,070, 101 genes, copy number 5 (broad region; genes not listed).
- chr4:153,034,211–153,091,563, 1 gene, copy number 5 (within-gene range 4–5): AC093599.1.
- chr5:24,729,379–29,882,945, 54 genes, copy number 6: AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, AC112172.2, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1.
- chr5:29,979,669–50,860,020, 266 genes, copy number 5–8 (broad region; genes not listed).
- chr7:70,972–1,747,954, 55 genes, copy number 7: AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1.
- chr7:1,838,586–1,849,931, 2 genes, copy number 7: AC104129.1, MIR4655.
- chr7:54,933,699–66,031,544, 294 genes, copy number 5–8 (broad region; genes not listed).
- chr8:2,493,876–2,926,689, 9 genes, copy number 6: AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1.
- chr8:3,373,353–3,700,628, 3 genes, copy number 6: AC026991.1, AC026991.2, RNA5SP251.
- chr8:38,600,661–38,704,855, 2 genes, copy number 6: RNF5P1, AC016813.1.
- chr8:38,744,020–38,744,131, 1 gene, copy number 6: Y_RNA.
- chr8:101,492,439–101,669,726, 1 gene, copy number 5 (within-gene range 2–5): GRHL2.
- chr8:101,562,008–102,124,907, 5 genes, copy number 5 (within-gene range 2–5): AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2.
- chr8:122,414,332–144,409,335, 398 genes, copy number 5–8 (within-gene range 4–11) (broad region; genes not listed).
- chr14:24,809,656–25,050,297, 1 gene, copy number 5 (within-gene range 4–5): STXBP6.
- chr14:25,124,467–78,060,278, 985 genes, copy number 5 (broad region; genes not listed).
- chr14:78,177,803–78,753,878, 6 genes, copy number 5: RNA5SP388, RPS26P48, AF099810.1, AC009396.2, AC009396.3, AC009396.1.
- chr14:105,785,505–106,264,715, 81 genes, copy number 6 (broad region; genes not listed).
- chr21:12,999,676–46,665,124, 735 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,168. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
